Gene-level copy-number profile of tumor specimen TCGA-22-5482-01A from TCGA case TCGA-22-5482, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.2 years (29,657 days).
Specimen TCGA-22-5482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.710c66be-2d8b-4b0c-8778-c290e81d67e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5482-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64a11b12-e2c3-4980-89e0-46f4690713ac

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 9,460; copy number 3: 3,298; copy number 4: 24,215; copy number 5: 10,651; copy number 6: 9,155; copy number 7: 541; copy number 9: 610; copy number 10: 820; copy number 12: 27; copy number 14: 994; copy number 16: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5482-01A-01D-1631-01): tumor purity 0.66, ploidy 2.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:2,444,684–2,849,105, 5 genes (within-gene range 0–4): KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,486 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,051,347–198,222,513, 999 genes, copy number 12–16 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr7:70,972–5,144,546, 110 genes, copy number 10 (broad region; genes not listed).
- chr16:4,257,186–5,235,822, 53 genes, copy number 14: TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1, MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1, PPL, SEC14L5, NAGPA-AS1, NAGPA, ALG1, C16orf89, AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,366,688, 4 genes, copy number 14: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3.
- chr20:87,250–31,723,989, 602 genes, copy number 9 (broad region; genes not listed).
- chr20:40,854,119–41,196,801, 6 genes, copy number 9: RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871.
- chr20:41,196,647–41,197,157, 2 genes, copy number 9: AL022394.1, RPL23AP81.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
